Gene-level copy-number profile of tumor specimen TCGA-PC-A5DM-01A from TCGA case TCGA-PC-A5DM, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 73.1 years (26,699 days).
Specimen TCGA-PC-A5DM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.8ecf7d26-b821-46d0-86c8-f7b734db3094.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PC-A5DM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/d3165f1d-b7dc-45ec-9b60-fb6a301f01cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,880; copy number 2: 21,168; copy number 3: 19,433; copy number 4: 11,931; copy number 5: 2,190; copy number 6: 1,048; copy number 7: 564; copy number 8: 141; copy number 9: 111; copy number 10: 12; copy number 11: 65; copy number 12: 136; copy number 13: 2; copy number 16: 65; copy number 20: 19; copy number 23: 4; copy number 32: 24.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,429,269–48,578,088, 6 genes: Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr13:63,034,668–63,783,904, 8 genes: AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,326 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:116,713,833–121,580,524, 111 genes, copy number 5–6 (broad region; genes not listed).
- chr3:80,442,081–90,261,708, 69 genes, copy number 7–32 (broad region; genes not listed).
- chr4:49,588,772–57,207,459, 119 genes, copy number 12 (broad region; genes not listed).
- chr4:57,490,808–66,897,371, 73 genes, copy number 9–16 (broad region; genes not listed).
- chr4:67,718,996–68,129,869, 13 genes, copy number 16: AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP, TMPRSS11D, TMPRSS11A, TMPRSS11GP, RNU6-95P, GCOM2, MTND2P41, TMPRSS11F, SYT14P1.
- chr5:58,198–14,532,128, 255 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:19,471,296–45,895,970, 357 genes, copy number 5–6 (broad region; genes not listed).
- chr6:40,501,631–60,546,660, 357 genes, copy number 5 (broad region; genes not listed).
- chr6:62,460,940–65,707,226, 26 genes, copy number 5 (within-gene range 3–5): DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr6:95,504,182–102,453,792, 63 genes, copy number 6–9 (broad region; genes not listed).
- chr6:104,687,241–105,083,332, 8 genes, copy number 7 (within-gene range 4–7): AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P.
- chr6:108,030,249–125,445,193, 250 genes, copy number 5–10 (broad region; genes not listed).
- chr6:128,500,527–129,516,566, 6 genes, copy number 6–8 (within-gene range 4–8): AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2.
- chr6:129,157,523–130,141,449, 11 genes, copy number 6 (within-gene range 4–6): BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3.
- chr6:144,706,733–154,605,954, 170 genes, copy number 5–7 (broad region; genes not listed).
- chr6:155,380,511–158,764,876, 48 genes, copy number 5: AL031773.1, NOX3, RNU7-152P, AL589693.1, MIR1202, AL512658.2, SNORD28B, AL512658.1, H3P28, AL355297.2, ARID1B, AL355297.3, MIR4466, AL355297.1, AL162578.1, AL049820.1, TMEM242, LDHAL6FP, AL390955.2, AL390955.1, AL117344.1, AL117344.2, ZDHHC14, MIR3692, SNX9, AL391863.2, AL391863.1, SNX9-AS1, HSPE1P26, RNU6-786P, SYNJ2, AL139330.1, SYNJ2-IT1, SERAC1, GTF2H5, TULP4, SRP72P2, AL360169.2, AL360169.3, AL360169.1, RN7SL173P, CACYBPP3, TMEM181, TATDN2P2, MIR7161, DYNLT1, SYTL3, AMZ2P2.
- chr8:19,404,161–22,798,616, 65 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:27,459,756–28,343,355, 29 genes, copy number 6: CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3, AC021678.1, AC021678.3, AC021678.2, RPL5P22, PNOC.
- chr8:36,987,977–47,202,897, 203 genes, copy number 5 (broad region; genes not listed).
- chr9:68,705,240–70,354,873, 26 genes, copy number 5 (within-gene range 3–5): PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5.
- chr9:109,015,135–116,402,321, 129 genes, copy number 5–7 (broad region; genes not listed).
- chr9:117,685,254–118,072,314, 6 genes, copy number 5 (within-gene range 4–5): RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1.
- chr12:22,395,088–23,188,807, 12 genes, copy number 6 (within-gene range 2–6): AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1.
- chr12:31,382,226–32,993,754, 55 genes, copy number 5: DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P, DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1.
- chr13:23,418,971–23,889,400, 6 genes, copy number 5 (within-gene range 4–5): SACS-AS1, LINC00327, LINC00352, TNFRSF19, MIPEP, MTCO3P2.
- chr13:33,333,679–40,666,641, 92 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:74,377,163–75,859,870, 19 genes, copy number 5–8: RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP.
- chr13:91,994,518–98,752,672, 87 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr13:99,087,819–114,337,626, 245 genes, copy number 5–8 (broad region; genes not listed).
- chr14:21,521,080–26,806,467, 299 genes, copy number 6–7 (broad region; genes not listed).
- chr16:35,085,896–35,912,516, 74 genes, copy number 9 (broad region; genes not listed).
- chr16:56,191,390–57,083,531, 46 genes, copy number 5 (within-gene range 3–5): GNAO1, DKFZP434H168, MIR3935, AC009102.4, AC009102.1, AC009102.3, AC009102.2, AMFR, AC092140.1, NUDT21, OGFOD1, AC092140.2, BBS2, MT4, MT3, MT2A, AC026461.3, MT1L, MT1E, MT1M, MT1JP, MT1A, MT1DP, MT1CP, AC026461.2, MT1B, MT1F, MT1G, MT1H, MT1IP, MT1X, AC026461.1, DPPA2P4, AC106779.1, NUP93, MIR138-2, SLC12A3, MIR6863, RPS24P17, HERPUD1, AC012181.2, AC012181.1, CETP, NLRC5, AC023825.1, AC023825.2.
- chr17:142,789–1,755,265, 57 genes, copy number 6: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2.
- chr17:7,839,904–9,643,447, 75 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:10,844,674–22,706,703, 445 genes, copy number 6–7 (broad region; genes not listed).
- chr18:5,721,812–9,538,114, 72 genes, copy number 10–11 (within-gene range 4–11) (broad region; genes not listed).
- chr19:27,638,483–32,244,083, 87 genes, copy number 5–6 (broad region; genes not listed).
- chr19:53,599,628–54,672,591, 139 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:17,493,905–17,968,980, 11 genes, copy number 5 (within-gene range 3–5): BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5.
- chr21:13,581,060–17,894,485, 94 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,003. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
